Gene-level copy-number profile of specimen HCM-CSHL-0803-C54-85A from HCMI case HCM-CSHL-0803-C54, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Carcinosarcoma, NOS; Tissue or organ of origin: Endometrium; AJCC pathologic stage: Stage IA; FIGO stage: Stage IA.
Specimen HCM-CSHL-0803-C54-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 9.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 2e92e9f4-8fcf-4834-8b18-d5cd5d3463de.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0803-C54-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,224 have no estimate.
https://portal.gdc.cancer.gov/files/46798f21-532c-4919-b21e-a5535a495288

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 11,853; copy number 2: 43,040; copy number 3: 3,290; copy number 4: 108; copy number 5: 44; copy number 6: 2; copy number 7: 1; copy number 19: 3; copy number 20: 28; copy number 21: 8; copy number 24: 5; copy number 29: 1; copy number 33: 2; copy number 34: 4; copy number 35: 10.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 108 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:18,839,599–19,680,966, 25 genes, copy number 5: TAS1R2, ALDH4A1, MIR4695, MIR1290, IFFO2, AL137127.1, UBR4, EMC1-AS1, EMC1, MRTO4, AKR7L, AKR7A3, AL035413.1, AKR7A2, RNU6-1099P, SLC66A1, CAPZB, RN7SL277P, MICOS10, RNU4-28P, AL031727.2, NBL1, MICOS10-NBL1, AL031727.1, HTR6.
- chr11:67,119,263–67,261,545, 3 genes, copy number 5: KDM2A, AP001885.1, AP001885.3.
- chr18:33,552,123–33,751,195, 2 genes, copy number 5–7: AC091198.1, ASXL3.
- chr19:27,638,483–30,713,538, 61 genes, copy number 19–35 (broad region; genes not listed).
- chr20:36,996,349–37,095,997, 1 gene, copy number 6 (within-gene range 3–6): RBL1.
- chr20:37,049,254–37,623,119, 16 genes, copy number 5–6: RPS27AP3, AL136172.1, MROH8, AL031659.1, RPN2, GHRH, MANBAL, SRC, RPL7AP14, BLCAP, NNAT, AL109614.1, PPIAP3, LINC01746, GLRXP1, LINC00489.

Autosomal genes at a single copy (total copy number 1): 11,853. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
